Gene-level copy-number profile of tumor specimen HCM-SANG-1334-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1334-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1334-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45254ae7-6820-451b-8300-5e1083f1e9cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1334-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/41bb23b7-6e4d-42b7-925a-c5f68abdb5fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 359; copy number 2: 57,295; copy number 3: 627; copy number 4: 1; copy number 5: 1; copy number 6: 4; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–1): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr14:22,147,995–22,552,156, 90 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 7: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr19:56,661,980–56,671,783, 1 gene, copy number 5: ZNF835.
- chr20:30,484,925–30,816,274, 4 genes, copy number 6: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Autosomal genes at a single copy (total copy number 1): 359. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
